CCDI case PBBWJS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/c5052de8-d151-43d4-a9c6-1dffe4a336e3

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Desmoplastic melanoma, malignant: ICD-O-3 morphology code: 8745/3; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 5.2 years (1,907 days).

Biospecimens (2 samples)
- Sample 0DJHDY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
